Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7376, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7376-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) ORAL CAVITY, FLOOR OF MOUTH, TONGUE, MANDIBULAR PERIOSTEUM, TONSILLAR PILLAR, PALATE, RESECTION: INVASIVE MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.5 CM IN GREATEST DIMENSION, INVOLVING THE DEEP MARGIN, WITHIN 1.0 MM OF THE RIGHT SURGICAL MARGIN AND WITHIN 5.0 MM OF THE LEFT SURGICAL MARGIN; ALL OTHER SURGICAL MARGINS NEGATIVE FOR TUMOR; LYMPHOVASCULAR INVASION IDENTIFIED; (SEE COMMENT).

2) LYMPH NODES, RIGHT NECK, LEVEL 1, DISSECTION: 3 LYMPH NODES AND SUBMANDIBULAR GLAND, NEGATIVE FOR MALIGNANCY. (0/3)

3) LYMPH NODES, RIGHT NECK, LEVEL 2, DISSECTION: 7 LYMPH NODES, AND SUBMANDIBULAR GLAND, NEGATIVE FOR MALIGNANCY. (0/7)

4) LYMPH NODES, RIGHT NECK, LEVEL 3, DISSECTION: METASTATIC CARCINOMA IN 1 OF 12 LYMPH NODES LESS THAN (0.1 CM) (1/12).

COMMENT: These findings correspond to AJCC pathologic stage III (pT2,N1,Mn/a).

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma

Summary of Findings:

Specimen Type: composite resection (floor of mouth, tongue, tonsillar pillar, palate, mandibular periosteum)

Tumor Site: floor of mouth

Tumor Size: 3.5 cm in greatest extent

Histologic Type: squamous cell carcinoma

Histologic Grade: moderately differentiated

Pathologic Staging (pTMN) III

Primary tumor (pT): pT2

Regional Lymph Nodes (pN): pN1

Number examined: 22

Numbered involved: 1

Extracapsular extension: No

Perineural invasion: (Select one) Yes

x No

[page 2 of 3]
Not evaluable

Bony/Cartilage Invasion: (Select one) Yes

x Not evaluable

HPV testing ordered: YES, PER [REDACTED] (performed on oral cavity and oropharyngeal squamous cell carcinomas)

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) Floor of mouth, tongue, mandibular periosteum, tonsillar pillar, palate stitched anterior; 2) Right neck, Level 1; 3) Right neck, Level 2, 4) Right neck, Level 3

GROSS DESCRIPTION:

1) SOURCE: Floor of Mouth, Tongue, Mandibular Periosteum, Tonsillar Pillar, Palate

Specimen received fresh, labeled "floor of mouth, tongue, mandibular periosteum, tonsillar pillar, palate stitched anterior," contains a complex mucosal resection measuring 4.5 cm anterior to posterior, 4.5 cm right to left, and 1.3 cm from superior to inferior. The specimen weighs 13.75 grams. The specimen is inked in the following fashion: anterior orange, posterior black, right red, left yellow, and deep blue. The resection margin has marked cautery artifact. The mucosal surface is white-pink and is remarkable for a 3.5 x 2.9 cm centrally located ulcerated lesion that abuts the left anterior margin. Sectioning through the specimen reveals the tumor to extend 0.9 cm deeply. Portions of tissue are taken for research, placed in glutaraldehyde, and frozen in a -80 degree freezer. On cut surface, the tumor is firm, white and circumscribed. The tumor is 4 mm to the red inked margin and is 1.8 cm to the posterior inked margin.

Representative sections are submitted as follows:

Summary of sections: 1A, red clipped vascular margin, anterior and posterior margins, 3/1; 1B, tumor to deep surface and left anterior margin, 2/1; 1C, right and deep margins, 3/1; 1D, deep margins, 2/1; 1E, left and deep margins, 2/1; 1F, posterior and left margins, 2/1.

2) SOURCE: Right Neck Level 1

Specimen is received fresh, labeled "level 1, right neck" and is an aggregate of fatty tissue containing submandibular gland and lymph nodes that measure 5.6 x 4.0 x 1.3 cm in aggregate. The tan, lobular, glandular

[page 3 of 3]
tissue measures 4.0 cm in greatest extent and has a glistening, lobular surface. Sectioning through the submandibular gland reveals no definitive lesion. Multiple candidate lymph nodes are identified and are entirely submitted. Representative portions of the submandibular gland are submitted.

Summary of sections: 2A and 2B, submandibular gland 2/1 each; 2C and 2D, multiple candidate lymph nodes, 3/1 each.

3) SOURCE: Right Neck Level 2

Specimen is received fresh, labeled "right neck, level 2" and is a portion of fibrovascular, fatty, and lymphoid tissue measuring 4.8 x 3.0 x 1.0 cm in aggregate. Sectioning through the tissue reveals multiple candidate lymph nodes, the largest of which measures 1.6 cm in greatest dimension. All lymphoid tissue is entirely submitted.

Summary of sections: 3A, 4 possible lymph nodes, 4/1; 3B, single largest lymph node, bisected, 2/1.

4) SOURCE: Right Neck Level 3

Specimen is received fresh, labeled "right neck, level 3" and is a portion of fibrofatty tissue containing lymph nodes that measure 8.4 x 2.0 x 0.7 cm. The tissue is searched for nodes and multiple candidate lymph nodes are identified and are entirely submitted.

Summary of sections: 4A, multiple lymph nodes, M/1; 4B, 4 possible lymph nodes, 4/1.

Source: NCI Genomic Data Commons file 0f87fb62-66a3-40c6-8726-799cb13098a9 (TCGA-CR-7376.0F1A7985-CCB8-485C-BA59-09E167BBC108.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).